Somatic mutation profile of tumor specimen ALCH-B1LY-TTP1-A (aliquot ALCH-B1LY-TTP1-A-1-0-D-A710-36) from ALCHEMIST case ALCH-B1LY, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 72.7 years (26,543 days).
Specimen ALCH-B1LY-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e362af9d-7fcf-4736-9de2-73643bf678ae.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B1LY-NB1-A (Blood Derived Normal), aliquot ALCH-B1LY-NB1-A-1-0-D-A710-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4a427298-f78c-4118-96c7-91c2a1c933be

The open-access MAF lists 40 somatic variants for this specimen: 23 protein-altering or splice-affecting, 11 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 20, Silent 11, Intron 4, 3'UTR 1, In Frame Del 1, Nonsense Mutation 1, Frame Shift Del 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANKRD30B | c.3112C>T p.Q1038* | Nonsense Mutation (SNP) | VAF 24/339 reads (7%) | catalogued as rs753111316; called by muse, mutect2
- HECW1 | c.4463C>T p.A1488V | Missense Mutation (SNP) | VAF 25/351 reads (7%) | SIFT tolerated (0.29); PolyPhen benign (0.079); catalogued as rs192568048; called by muse, mutect2
- MEX3A | c.1054G>C p.E352Q | Missense Mutation (SNP) | VAF 11/232 reads (5%) | SIFT tolerated (0.48); PolyPhen probably damaging (0.932); catalogued as rs1457873110; called by muse, mutect2
- MYCBP2 | c.8479C>T p.P2827S (on ENST00000357337; = p.P2865S on NM_015057.5) | Missense Mutation (SNP) | VAF 49/434 reads (11%) | SIFT tolerated, low confidence (0.24); PolyPhen probably damaging (0.979); catalogued as rs1170240057, COSV100631219; called by muse, mutect2, varscan2
- QRICH1 | c.1852T>C p.S618P | Missense Mutation (SNP) | VAF 5/54 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs866353908, COSV100455242; called by muse, mutect2
- RYR2 | c.3371C>T p.P1124L | Missense Mutation (SNP) | VAF 24/464 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs779640835, COSV100769203, COSV63662051; ClinVar: uncertain significance; called by muse, mutect2
- RYR2 | c.8021G>T p.G2674V | Missense Mutation (SNP) | VAF 108/528 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV63680647; called by muse, mutect2, varscan2
- SLC1A3 | c.1319C>A p.A440E | Missense Mutation (SNP) | VAF 55/393 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs947894847; called by muse, mutect2, varscan2
- TTN | c.758C>T p.T253I | Missense Mutation (SNP) | VAF 56/445 reads (13%) | PolyPhen benign (0.319); catalogued as rs945095401; called by muse, mutect2, varscan2
- ZFYVE26 | c.1704C>G p.D568E | Missense Mutation (SNP) | VAF 76/693 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.018); catalogued as rs373958917; called by muse, mutect2, varscan2
- ZSWIM8 | c.2138C>T p.P713L | Missense Mutation (SNP) | VAF 9/112 reads (8%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); catalogued as rs761837522, COSV101289746; called by muse, mutect2
- ACSL1 | c.1636C>T p.P546S | Missense Mutation (SNP) | VAF 42/234 reads (18%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.491); called by muse, mutect2, varscan2
- CEP131 | c.815C>T p.T272I | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT deleterious (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- CFAP53 | c.637G>A p.E213K | Missense Mutation (SNP) | VAF 32/473 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.429); called by muse, mutect2
- DPY19L3 | c.1079A>G p.N360S | Missense Mutation (SNP) | VAF 14/278 reads (5%) | SIFT tolerated (0.38); PolyPhen benign (0.001); called by muse, mutect2
- EIF4G1 | c.2308A>G p.K770E (on ENST00000346169 / NM_198241.3; = p.K575E on NM_004953.5) | Missense Mutation (SNP) | VAF 20/302 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- MYO7B | c.981C>A p.H327Q | Missense Mutation (SNP) | VAF 26/147 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCF11 | c.2919_2936del p.N974_N979del | In Frame Del (DEL) | VAF 29/293 reads (10%) | called by mutect2, pindel
- PKNOX2 | c.935T>C p.M312T | Missense Mutation (SNP) | VAF 15/94 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.249); called by muse, mutect2, varscan2
- PLD1 | c.1655G>A p.G552E | Missense Mutation (SNP) | VAF 86/614 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- RNASE11 | c.118G>C p.A40P | Missense Mutation (SNP) | VAF 16/356 reads (4%) | SIFT tolerated (0.12); PolyPhen benign (0.013); called by muse, mutect2
- STK11 | c.54del p.M18Ifs*33 | Frame Shift Del (DEL) | VAF 9/88 reads (10%) | called by mutect2, pindel, varscan2
- TELO2 | c.923C>G p.S308C | Missense Mutation (SNP) | VAF 14/97 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.525); called by muse, mutect2, varscan2
- ARHGAP32 | c.5160T>G p.S1720= (on ENST00000310343 / NM_001378025.1; = p.S1371= on NM_014715.4) | Silent (SNP) | VAF 31/188 reads (16%) | called by muse, mutect2, varscan2
- CEP126 | c.552C>T p.H184= | Silent (SNP) | VAF 34/301 reads (11%) | catalogued as rs1165654190; called by muse, mutect2, varscan2
- GANC | c.2370C>T p.G790= | Silent (SNP) | VAF 30/346 reads (9%) | called by muse, mutect2
- KCNN3 | c.2175C>T p.S725= (on ENST00000618040 / NM_001204087.1; = p.S710= on NM_002249.6) | Silent (SNP) | VAF 13/74 reads (18%) | catalogued as rs752464816, COSV55213271; called by muse, mutect2, varscan2
- NINL | c.3444A>G p.Q1148= | Silent (SNP) | VAF 12/224 reads (5%) | catalogued as rs1316430360; called by muse, mutect2
- PALB2 | c.945G>T p.L315= | Silent (SNP) | VAF 25/164 reads (15%) | catalogued as rs1555461529; ClinVar: likely benign; called by muse, mutect2, varscan2
- PPP1R3F | c.1203T>C p.S401= | Silent (SNP) | VAF 6/28 reads (21%) | catalogued as rs1333193884; called by muse, varscan2
- RASEF | c.1608T>C p.F536= | Silent (SNP) | VAF 24/190 reads (13%) | called by muse, mutect2, varscan2
- SLC5A7 | c.267T>C p.I89= | Silent (SNP) | VAF 28/203 reads (14%) | catalogued as rs1246228626; called by muse, mutect2, varscan2
- STAT3 | c.1164C>T p.G388= | Silent (SNP) | VAF 132/682 reads (19%) | called by muse, mutect2, varscan2
- TMC7 | c.1503C>T p.F501= | Silent (SNP) | VAF 23/234 reads (10%) | catalogued as rs757524130, COSV100432917; called by muse, mutect2, varscan2
- AKT2 | c.639+190G>A | Intron (SNP) | VAF 23/112 reads (21%) | called by muse, mutect2, varscan2
- CCDC158 | c.*4G>A | 3'UTR (SNP) | VAF 20/241 reads (8%) | catalogued as rs748523778; called by muse, mutect2
- FMR1 | c.1472-39A>T | Intron (SNP) | VAF 14/244 reads (6%) | catalogued as rs1167026205, COSV54424178; called by muse, mutect2
- MIR513A2 | n.69T>C | RNA (SNP) | VAF 49/302 reads (16%) | called by muse, mutect2, varscan2
- PSD3 | c.2176-28238G>A | Intron (SNP) | VAF 14/131 reads (11%) | called by muse, mutect2, varscan2
- SLC22A8 | c.885+70G>T | Intron (SNP) | VAF 7/60 reads (12%) | called by muse, mutect2, varscan2
